Somatic mutation profile of tumor specimen 0DKDDG from CCDI case PBBYAR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.2 years (2,250 days).
Specimen 0DKDDG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7a10173-26a9-4f94-8652-353e9e84fcba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKDBZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d145bc1-3008-40a9-b5ec-317f87974a0a

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Intron 2, RNA 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.3269C>T p.A1090V | Missense Mutation (SNP) | VAF 60/654 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.273); catalogued as rs143392573; called by muse, mutect2
- BDP1 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 113/683 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); catalogued as COSV100703107, COSV62432329; called by muse, mutect2, varscan2
- C1orf131 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 32/486 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1428360256; called by muse, mutect2
- C22orf42 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 64/358 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as rs777571331, COSV66076077; called by muse, mutect2, varscan2
- DHX33 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 138/987 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.298); catalogued as rs774779006; called by muse, mutect2, varscan2
- MIPEP | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 86/422 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs201343071; called by muse, mutect2, varscan2
- NBEAL2 | c.7129G>A p.A2377T | Missense Mutation (SNP) | VAF 97/557 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs939407511; called by muse, mutect2, varscan2
- PCDHB7 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 142/769 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.055); catalogued as rs267600426, COSV50753987; called by muse, mutect2, varscan2
- RACGAP1 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 103/538 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs200432429; called by muse, mutect2, varscan2
- SPATA31E1 | c.4168G>T p.V1390F | Missense Mutation (SNP) | VAF 96/483 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.299); catalogued as rs1463593723; called by muse, mutect2, varscan2
- TRIM64C | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 141/882 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs546301976; called by muse, mutect2, varscan2
- ADAMTS19 | c.1315A>G p.I439V | Missense Mutation (SNP) | VAF 112/670 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ASCC3 | c.2507G>C p.G836A | Missense Mutation (SNP) | VAF 39/524 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAMKMT | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 85/558 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MC3R | c.724G>C p.V242L | Missense Mutation (SNP) | VAF 73/1132 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.253); called by muse, mutect2
- THAP5 | c.31A>T p.K11* | Nonsense Mutation (SNP) | VAF 146/1317 reads (11%) | called by muse, mutect2, varscan2
- CACNA1B | c.1257G>A p.A419= | Silent (SNP) | VAF 70/439 reads (16%) | catalogued as rs200466269, COSV53127589, COSV53141376; called by muse, mutect2, varscan2
- SEMA3A | c.192G>A p.E64= | Silent (SNP) | VAF 45/1300 reads (3%) | called by muse, mutect2
- SLC27A1 | c.525C>T p.G175= | Silent (SNP) | VAF 89/632 reads (14%) | catalogued as rs1184596250, COSV53097777; called by muse, mutect2, varscan2
- SLC28A1 | c.132C>T p.P44= | Silent (SNP) | VAF 82/590 reads (14%) | catalogued as rs17215892, COSV104379473; called by muse, mutect2, varscan2
- AL731532.1 | n.1918T>C | RNA (SNP) | VAF 79/319 reads (25%) | called by muse, mutect2, varscan2
- CNGA4 | c.1267+50G>C | Intron (SNP) | VAF 18/224 reads (8%) | catalogued as COSV101171883; called by muse, mutect2
- PEX1 | c.2784-61G>C | Intron (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- SFXN2 | c.*59C>T | 3'UTR (SNP) | VAF 58/165 reads (35%) | catalogued as rs1172029693; called by muse, mutect2, varscan2
- SPATA31C2 | n.2084T>A | RNA (SNP) | VAF 197/1154 reads (17%) | called by muse, mutect2, varscan2
